Surgical pathology report (de-identified scan), TCGA case TCGA-B2-4099, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B2-4099-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

Right kidney

CLINICAL NOTES

PRE-OP DIAGNOSIS: Renal mass.

GROSS DESCRIPTION

Received fresh for tissue procurement labeled "right kidney" is a 309 gram, 10.0 x 5.8 x 4.8 cm right kidney with attached, probe-patent 3 cm ureter averaging 0.3 cm in diameter

and a moderate amount of attached perinephric adipose tissue.

Renal

capsule is delicate and strips with each from the underlying cortical surface. The specimen is bisected to reveal a central, moderate well circumscribed, 3.0 x 2.8 x 2.5 cm yellow orange tumor mass. The tumor approaches the renal pelvis which is glistening tan-white, but does not compress or extend into it. The tumor is present to within 0.5 cm of the inked capsular surface of the specimen (see blocks 2 and 3). Remaining parenchyma is uniform tan-red-brown with a well defined cortical medullary junction and a maximal cortical thickness of 1.0 cm. A single 0.3 cm cortical

cyst

is noted inferiorly. No adrenal tissue is present. A portion of the tumor and a portion of normal parenchyma are submitted for tissue procurement as requested. Representative sections are submitted in eight blocks as labeled. RS-8.

BLOCK SUMMARY: 1 - Vascular and ureteral margins; 2-3 - tumor to inked capsular surface of specimen; 4 - tumor to renal pelvis; 5 - tumor to adjacent parenchyma; 6 - renal pelvis; 7-8 - random from remainder of specimen.

[page 2 of 2]
[REDACTED]

MICROSCOPIC DESCRIPTION

Histologic type: Clear cell renal cortical carcinoma.
Histologic grade (Fuhrman Nuclear Grade): 2-3.
Primary tumor (pT): The tumor measures 3.0 cm, pT1a.
Margins of resection: Negative.
Regional lymph nodes (pN): Cannot be assessed.
Distant metastasis (pM): Cannot be assessed.
Adrenal gland: Not present.
Vascular invasion: Negative.
Non-neoplastic kidney: Single small cortical cyst.
Other findings: None.

4

DIAGNOSIS

Right kidney, nephrectomy - Kidney with 3.0 cm clear cell renal cortical carcinoma, Fuhrman nuclear grade 2-3, confined to the kidney.

[REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file 83b61d68-19e7-46ea-9d5e-931a1362ad0e (TCGA-B2-4099.4EF87AF2-B6AE-44EC-B149-7170951E9D60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).